Surgical pathology report (de-identified scan), TCGA case TCGA-FE-A233, project TCGA-THCA (Thyroid Carcinoma), tissue source site Ohio State University, specimen TCGA-FE-A233-01A (Primary Tumor).

[page 1 of 4]
HPA-1 Discrepancy		✓
Case L (Fricke)		
	lw	4/8/11

Specimen Description

Surgical Pathology Report

Patient Name: [REDACTED]
Accession #: [REDACTED]
Med. Rec #: [REDACTED]
Submitting Physician: [REDACTED]

*****Clinical History*****
History: Right thyroid mass.

ICD-0-3

carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9 lw 4/8/11

*****Final Pathologic Diagnosis*****

- A. Right thyroid lobe, excision:
- Papillary Thyroid Carcinoma see synoptic report.
- B. Left thyroid lobe, excision:
- No Pathologic Change.

Electronically Signed By
[REDACTED]
[REDACTED]

*****Synoptic Report*****

SYNOPTIC REPORT FOR THYROID CANCER:
Specimen type: total thyroidectomy
Tumor location: right lobe
Tumor size: 2.3 x 2.2 x 1.5 cm.
Histologic type: papillary thyroid carcinoma, no special type
Lymphatic/vascular invasion: absent
Capsular invasion: absent
Tumor extent:
Confined to the thyroid: yes
Multifocal: no
Lymph nodes:
Total number examined: none
pTNM: pT2 Nx Mx.

The above synoptic report complies, in slightly modified form, with the guidelines of the College of American Pathologists and the Association of Directors of Anatomic and Surgical Pathology for the reporting of cancer specimens

[page 2 of 4]
Sex: F

Specimen Description

Surgical Pathology Report

*****Clinical History*****

History: Right thyroid mass.

*****Final Pathologic Diagnosis*****

- A. Right thyroid lobe, excision:
- Papillary Thyroid Carcinoma see synoptic report.
- B. Left thyroid lobe, excision:
- No Pathologic Change.

*****Synoptic Report*****

SYNOPTIC REPORT FOR THYROID CANCER:

Specimen type: total thyroidectomy

Tumor location: right lobe

Tumor size: 2.3 x 2.2 x 1.5 cm.

Histologic type: papillary thyroid carcinoma, no special type

Lymphatic/vascular invasion: absent

Capsular invasion: absent

Tumor extent:

Confined to the thyroid: yes

Multifocal: no

Lymph nodes:

Total number examined: none

pTNM: pT2 Nx Mx.

The above synoptic report complies, in slightly modified form, with the guidelines of the College of American Pathologists and the Association of Directors of Anatomic and Surgical Pathology for the reporting of cancer specimens

[page 3 of 4]
*****INTRAOPERATIVE CONSULTATION DIAGNOSIS:*****

AF1. Right thyroid lobe stitch-1=superior pole-2=inferior pole:
(FROZEN SECTION PERFORMED)

- Papillary thyroid carcinoma.

Examining pathologist [REDACTED]

*****SPECIMEN(S) RECEIVED:*****

SR

A: Thyroid, REG

B: Thyroid, REG

*****GROSS DESCRIPTION:*****

The specimens are received in two properly labeled containers, one of which is submitted for frozen section, with the patient's name and accession number.

A. The specimen is designated 3right thyroid lobe4 and consists of a 10.55 gram thyroid lobe that is 4.5 x 2.5 x 1.8 cm and is oriented with one stitch designating superior pole and two stitches designating inferior pole. The external surface is inked as follows: superior half=blue, inferior half=black and isthmic margin=yellow. Cut section reveals a pale tan granular mass in the superior half of the right thyroid lobe that is 1.5 cm from the isthmic margin. The mass is 2.3 x 2.2 x 1.5 cm and focally abuts the blue inked external surface. The mass does not appear to be encapsulated and there are no areas of hemorrhage or necrosis. The surrounding uninvolved thyroid parenchyma is grossly unremarkable. There are no parathyroid glands or lymph nodes.

Summary of Cassettes: AF1, frozen section, mass; A1-2, mass and blue inked external surface, perpendicular; A3, mass and adjacent uninvolved thyroid; A4, isthmic edge, shave; A5, uninvolved thyroid

B. The specimen is designated 3left thyroid lobe4 and consists of a 7.6 gram thyroid lobe that is 4.2 x 3.3 x 2.0 cm. The external surface is dark pink and focally shaggy. There are no lymph nodes or parathyroid glands identified and the specimen is inked black and the isthmic edge is inked orange. Cut section reveals red-brown thyroid parenchyma with no discrete lesions. RS 3

Summary of Cassettes: B1, isthmic edge, shave; B2-3, thyroid

Lab Use Only: [REDACTED]

Gross description by: [REDACTED]

[REDACTED]

[page 4 of 4]
[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file c18967b0-34f1-4030-9bba-d548ad7d9868 (TCGA-FE-A233.BABD0B38-955F-4F79-8851-1967C6E17F72.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).